Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1JK, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1JK-01A (Primary Tumor).

ICD-0-3

Carcinoma, infiltrating ductal, NOS 8500/3

Site: breast, NOS C50.9 3/11/11 for

page 1 / 1

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Multiple organ resection – left breast

Unit in charge:

Physician in charge:

Material collected or

Material received on:

Expected time of examination: 8 working days

Clinical diagnosis:

Examination performed on:

Results of immunohistochemical examination:

No estrogen receptors found in the neoplastic cell nuclei. Progesterone receptors found in less than 10% of the neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO. Negative reaction in invasive cancerous cells (Score = 1+). Estrogen receptor was stained twice.

Compliance validated by:

Examination performed on:

Macroscopic description:

Right breast sized 15 x 9 x 3 cm removed along with axillary tissues sized 7 x 4 x 1 cm and a skin flap of 11 x 7 cm. Weight 650 g. Tumour sized 3.2 x 2.0 x 3.0 cm on the border of the upper quadrants, placed 2.0 cm from the upper edge and 1.5 cm from the base.

Microscopic description:

Carcinoma ductale invasivum NHG3 (3 + 3 + 3: 21 mitoses/10 HPF - visual area of 0.55 mm). Glandular tissue off the tumour showing lesions of the type mastopathia fibrosa et cystica, hyperplasia ductalis simplex (UDH).

Axillary lymph nodes:

Sinus histiocytosis cum microcalcificationes lymphonodorum (No XIII).

Histopathological diagnosis:

Carcinoma ductale invasivum mammae sinistrae. Invasive ductal carcinoma of the left breast. (NHG3, pT2, pN0).

Compliance validated by

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 3d8f7ba2-fe5a-48ac-abce-72cebaa6f23c (TCGA-D8-A1JK.1841FEE0-EC36-4EC4-8B5E-6D340C80735B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).